Surgical pathology report (de-identified scan), TCGA case TCGA-32-4213, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4213-01A (Primary Tumor).

[page 1 of 2]
NEUROPATHOLOGY REPORT

TCGA-32-4213

SPECIMEN SOURCE:

1. Right frontal tumor
2. Right frontal tumor

CLINICAL DIAGNOSIS:

Subdural hematoma

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "right frontal tumor" are multiple pink-tan soft tissue fragments aggregating to 1.0 x 0.6 x 0.1 cm. A smear is performed and the specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

2. Received in formalin labeled with the patient's name and "right frontal tumor" are multiple tan-brown soft tissue fragments aggregating to 4.0 x 3.5 x 2.0 cm. The larger fragments are serially sectioned and representative sections are submitted in two cassettes.

MICROSCOPIC DESCRIPTION:

1, 2. Permanent section of the frozen section specimen demonstrates a markedly hypercellular glial neoplasm that is composed of moderately to markedly atypical astrocytes. The neoplastic cells demonstrate significant nuclear pleomorphism and hyperchromatic nuclei with irregular contours. Numerous scattered mitotic figures are seen. The tumor demonstrates robust microvascular proliferation and areas of necrosis, including pseudopalisading necrosis. The neoplastic cells diffusely infiltrate the adjacent brain parenchyma. The histologic features are consistent with a glioblastoma.

The MGMT immunostain demonstrates patchy regional immunoreactivity at overall approximately 25-50% of neoplastic cells.

[page 2 of 2]
EUROPATHOLOGY REPORT

DIAGNOSIS:

1, 2. RIGHT FRONTAL TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA, (ASTROCYTOMA GRADE IV).
- 25-50% IMMUNOREACTIVITY FOR MGMT.

CPT: 88307 X 2, 88331, 88342

Dictated by:
Verified by:

Source: NCI Genomic Data Commons file 828b6670-0b9f-4469-9506-c9ba74cca3ef (TCGA-32-4213.918246A7-4AE5-463D-B889-011E0EE45EFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).